Somatic mutation profile of tumor specimen BA2747D (aliquot aq-BA2747D) from BEATAML1.0 case 2205, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.6 years (31,281 days).
Specimen BA2747D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9128e251-a841-45b9-b804-07ae0cc68bd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2158D (Solid Tissue Normal), aliquot aq-BA2158D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d0ddaa8-719f-4d91-9431-296293b684af

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA10 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201368392, COSV53368825; called by muse, mutect2, varscan2
- DNAH9 | c.10049G>A p.R3350H | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761582456; called by muse, mutect2, varscan2
- KCNH5 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 21/276 reads (8%) | catalogued as COSV59765043; called by muse, mutect2
- JPH4 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- PERM1 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by mutect2, varscan2
- EN1 | c.168C>T p.P56= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SERINC4 | c.1104C>T p.P368= | Silent (SNP) | VAF 10/177 reads (6%) | catalogued as rs1255023345; called by muse, mutect2
- EIF4H | c.-2A>G | 5'UTR (SNP) | VAF 35/68 reads (51%) | catalogued as rs1554707317; called by muse, mutect2, varscan2
- KLC1 | c.1651-7075C>T | Intron (SNP) | VAF 76/182 reads (42%) | catalogued as rs773920579; called by muse, mutect2, varscan2
